Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A689, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A689-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 2
SEX: M

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Right pheochromocytoma. Right posterior approach laparoscopic retroperitoneal adrenalectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "Right adrenal gland tissue procurement". Received in a medium container of formalin is a 14.465 (untrimmed weight) adrenal gland consisting of a single lesion, 3.0 x up to 2.6 cm x up to 1.2 cm as well as attached stringy adipose tissue and atrophic-appearing possible normal adrenal gland, 3.0 x 2.0 x 0.15

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 3
SEX: M

ACCESSION:

OPER DATE:

REQ DOC:

cm in thickness. The entire specimen is inked black on its excision surface and serially sectioned to reveal a mottled white-pink focally hemorrhagic fish flesh appearance within the mass. The mass appears rimmed circumferentially by 0.1 cm of orange tissue similar in the appearance to unremarkable adrenal gland.

1A-C. Full cross sections of the encapsulated mass showing mass to margins. 1D and E. Serial sections of thinned/atrophic appearing attached adrenal tissue. 20% of adrenal tissue and adipose retained. Mass submitted entirely.

2. "Additional tissue, right adrenal gland." Received in formalin in a tall small container are two ragged portions of cauterized, pink-tan fibroadipose tissue (2.2 x 0.8 x 0.3 cm and 1.6 x 1.1 x 0.2 cm).

PROCEDURE: SPDX

VERIFIED BY:

1. Right adrenal gland, adrenalectomy: Pheochromocytoma (3.0 cm), see comment.
2. Right adrenal gland, "additional tissue", excision: Benign adrenal gland.

COMMENT:

The capsule of the adrenal gland was fragmented upon receipt in pathology and the pheochromocytoma extends to the inked edges of the specimen. This may represent a true positive margin, although the normal adrenal gland in specimen #2 may invalidate this positive margin.

I, _____, the signing staff pathologist, have personally examined and interpreted the slides from this case.

ACCESSION:

REQ DOC:

Criteria	4/22/13	Yes	No

Source: NCI Genomic Data Commons file e966d610-9042-4d1b-8d57-030e8643d555 (TCGA-RW-A689.0FC05624-ECAE-4109-B5FA-26DF9D8C5E27.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).